Somatic mutation profile of tumor specimen MP2PRT-PARPCA-TMP1-A (aliquot MP2PRT-PARPCA-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPCA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,176 days).
Specimen MP2PRT-PARPCA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71f19f06-6d95-497a-8c6b-427668a76b42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPCA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPCA-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8bfa668-3b23-4d87-9d42-97a766a42837

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 119/328 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 177/496 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1555933643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDX27 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 26/567 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65629434; called by muse, mutect2
- MLF1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 90/272 reads (33%) | catalogued as rs375897249; called by muse, mutect2, varscan2
- MYH6 | c.4624C>A p.L1542M | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs750721562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1451079733, COSV51959348, COSV99215021; called by muse, mutect2, varscan2
- TMEM231 | c.438C>T p.H146= (on ENST00000258173 / NM_001077418.3; = p.H175= on NM_001077416.2) | Splice Region (SNP) | VAF 22/133 reads (17%) | catalogued as rs1358196751; called by muse, varscan2
- TRPC7 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.149); catalogued as rs771143978, COSV61456542; called by muse, mutect2, varscan2
- IGKJ1 | c.2_3insTT p.W2Ffs*? | Frame Shift Ins (INS) | VAF 104/194 reads (54%) | called by mutect2, varscan2
- IGKJ1 | c.1delinsATT p.W2Ffs*? | Frame Shift Ins (INS) | VAF 125/230 reads (54%) | called by mutect2*, pindel, varscan2*
- RBM15B | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 270/805 reads (34%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PI4K2B | c.1422G>A p.R474= | Silent (SNP) | VAF 79/284 reads (28%) | catalogued as rs1425335615; called by muse, mutect2, varscan2
- SLC2A8 | c.51C>T p.G17= | Silent (SNP) | VAF 18/636 reads (3%) | called by muse, mutect2
- USP31 | c.333C>A p.P111= | Silent (SNP) | VAF 89/223 reads (40%) | called by muse, mutect2, varscan2
